Somatic mutation profile of tumor specimen TCGA-13-0714-01A (aliquot TCGA-13-0714-01A-01W-0371-08) from TCGA case TCGA-13-0714, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.1 years (20,109 days).
Specimen TCGA-13-0714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 211d70cd-7010-4264-8dc5-af31939dad35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0714-10B (Blood Derived Normal), aliquot TCGA-13-0714-10B-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0c0a112-73d6-4a40-b358-01097d005da4

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 20/38 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- LATS1 | c.3082C>A p.P1028T | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53586504, COSV53587838; called by muse, mutect2, varscan2
- MYO3B | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV58695492; called by muse, mutect2, varscan2
- PAX3 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs745673188, COSV60586370; called by muse, varscan2
- TTBK2 | c.2232C>A p.N744K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV99142449; called by muse, mutect2, varscan2
